Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A891, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A891-01A (Primary Tumor).

[page 1 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC.

PROCEDURE:

VERIFIED BY:

-year-old male with a history of dysphagia and epigastric pain diagnosed with carcinoma at the esophagogastric junction, presenting for gastrectomy and colon interposition. The patient did not have preoperative chemotherapy or radiation.

PROCEDURE:

VERIFIED BY:

1. "Retroperitoneal nodule. Rule out metastatic carcinoma." Received in a small container is a 1.2 x 0.8 x 0.3 cm yellow soft tissue fragment. Serially sectioned. No mass identified.
Frozen section control.
2. "Celiac/left gastric lymph node ? CA." Received in a small container is a 1.0 x 0.5 x 0.2 cm red-brown-yellow soft tissue fragment.
Frozen section control.
3. "Esophagus and proximal stomach." Received in a large container is an esophagogastrectomy including 8 cm of esophagus and an 8.2 x 5.0 cm portion of stomach. A 6.8 x 5.5 x 2.3 cm ulcerated, partially necrotic tumor mass arises from what appears to be the esophagogastric junction. Tumor extends approximately 4.3 cm into the stomach and 2.0 cm into the esophagus above the EG junction and involves approximately half of the esophageal circumference. Tumor is multinodular and the edges are rolled and somewhat serpiginous. The tumor is 4.0 cm from the proximal esophagus margin and approximately 1 to 1.5 cm from the gastric margin. Portions of gastric margin at closest approach are sampled for frozen section. Sectioning reveals the tumor appears to penetrate through the underlying muscle and into fat. However, the leading edge of the tumor is surrounded by white-tan probable fibrosis and there is no clear border between fibrosis and tumor. Tumor extends to within 0.5 cm, closest to the deep fat/radial margin. Multiple enlarged lymph nodes are noted beneath the tumor.
3A - 3C. Gastric margin.
Frozen section control.
- 3D. Mass with esophagus and deep penetration.
- 3E. Mass and deepest penetration.
- 3F. Mass and proximal esophagus.
- 3G. Mass and distal stomach.
- 3H. Mass and deep penetration.
- 3I. Fat beneath tumor at deepest penetration.
- 3J. Largest lymph node, gastric cardia.
- 3L. Two matted lymph nodes, bisected.
- 3M & 3N. Possible lymph nodes, perigastric.
- 3O. One periesophageal lymph node, bisected.
- 3P. Possible periesophageal lymph nodes.
- 3Q. Section of normal EG junction and proximal esophagus.
- 3R. Normal stomach.
4. "Greater omental." Received in a large container is a 19 x 12 x 1.8 cm piece of grossly unremarkable omental fat. Sectioning reveals unremarkable

ICD-O-3

Adenocarcinoma NOS 8140/3
Site: Distal third of esophagus C15.9
QJ 11/12/13

[page 2 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 3
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

tan-yellow fibroadipose tissue and vessels. No lesions.
5. "Cervical margin." Received in a small container is a 1.8 x 1.0 x 0.5 cm
U-shaped portion of grey-tan mucosa with staples. Margin opposite staples
shaved.
Staples retained.

FROZEN SECTION REPORT:

- 1. Negative for carcinoma.
2. Negative for carcinoma.
3A - 3C. Stomach margins negative for carcinoma.

I, , have reviewed and interpreted the frozen section
material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE:

VERIFIED BY:

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma.

If adenocarcinoma, it is arising in: GE junction.

Depth of invasion: Adventitia.

Number of positive lymph nodes: 2/30

Extranodal metastasis: Unknown.

Pattern of invasion: Infiltrative and expansile.

Esophageal and gastric resection margins involved: No.

Deep resection margin involved: No.

TNM classification: T3 N1 Mx

[page 3 of 3]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 4
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

1. Retroperitoneal nodule, excision: Negative for neoplasm.
2. Celiac/left gastric lymph node, excision: One lymph node negative for neoplasm.
3. Esophagus and proximal stomach, resection: Transmurally invasive adenocarcinoma arising at the gastroesophageal junction. Metastatic carcinoma in two of 29 lymph nodes with extracapsular extension. Perineural invasion identified. Margins negative for neoplasm. No Barrett's mucosa identified. Please see template above.
4. Omentum, excision: Negative for neoplasm.
5. Cervical margin, excision: Negative for neoplasm.

I, , the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Qual/Sync/Qual/Primary Muted		/

Source: NCI Genomic Data Commons file e2fdb859-f3cc-44b5-ab02-07c88d119bc3 (TCGA-L5-A891.87079493-02F1-4EB7-9C34-C174C84B8FEE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).